TCGA case TCGA-LN-A4A6 — Esophageal Carcinoma (TCGA-ESCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Esophagus; Tissue source site: ILSBIO. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ffcfa005-a04f-458e-9d1d-86143dd823e5

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Country of residence at enrollment: Vietnam; Age at index: 65 years; Vital status: Alive; Country of birth: Vietnam.

Diagnoses (2)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C15.5; Tissue or organ of origin: Lower third of esophagus; Site of resection or biopsy: Esophagus, NOS; Classification of tumor: primary; Age at diagnosis: 65.7 years (24,011 days); Year of diagnosis: 2012; Method of diagnosis: Surgical Resection; AJCC staging edition: 6th; AJCC clinical T: T2; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage II; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 391 days (1.1 years); Sites of involvement: Esophagus, Lower Third.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine; Days to treatment start: 69 days; Days to treatment end: 96 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 146 days; Days to treatment end: 178 days; Treatment dose: 45 Gy; Treatment outcome: Complete Response; Number of fractions: 25; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Surgery, NOS.
   Recorded as not given: Chemotherapy, preoperative; Radiation Therapy, NOS, preoperative.
2. Recurrence of diagnosis 1 (Squamous cell carcinoma, NOS). Age at diagnosis: 66.2 years (24,169 days); Days to diagnosis: 158 days; Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (4 entries)
- Days to follow up: 3 days; Disease response: Tumor Free.
- Day 158 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 158 days.
- Days to follow up: 391 days (1.1 years); Disease response: Tumor Free.
- Karnofsky performance status: 40.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 72 kg; Height: 176 cm; BMI: 23.2.

Exposures
- Alcohol history: Yes; Alcohol drinks per day: 2; Alcohol days per week: 7.
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 20; Tobacco smoking quit year: 2011; Age at onset: 25.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-LN-A4A6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 320 mg.
  Slide TCGA-LN-A4A6-01A-01-TSA: Section location: Top; Percent tumor cells: 65; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 30; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-LN-A4A6-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-LN-A4A6-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Tobacco smoking history indicator: 4; Alcohol consumption frequency: 7; History reflux disease indicator: No; Number of relatives diagnosed: 0.
- Primary pathology: Esophageal tumor location centered: Distal; Histologic diagnosis: Esophagus Squamous Cell Carcinoma; Lymph nodes examined: No; Patient to undergo surgery: Surgery already performed.
- Primary pathology, Esophageal tumor involvement sites: Esophageal tumor location involved: Distal.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 391 days; disease-specific survival: no event (censored), 391 days; disease-free interval: event (new tumor event after initially disease-free), 158 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 158 days.
